TARGET case TARGET-30-PADLPR — Neuroblastoma (TARGET-NBL)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neuroepitheliomatous Neoplasms; Primary site: Peripheral nerves and autonomic nervous system. Index date: not stated by GDC for this case (day counts are relative to an unstated reference).
https://portal.gdc.cancer.gov/cases/0317fb8f-3690-5400-89e4-38ea2669404c

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Vital status: Dead.

Diagnoses (1)
1. Neuroblastoma, NOS: ICD-O-3 morphology code: 9500/3; Age at diagnosis: 2.2 years (806 days); Year of diagnosis: 1993; Days to last follow up: 444 days (1.2 years); INSS stage: Stage 4.

Biospecimens (2 samples)
- Sample TARGET-30-PADLPR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-30-PADLPR-14A: Sample type: Bone Marrow Normal; Tissue type: Normal; Specimen type: Bone Marrow NOS.
